Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3519, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3519-01A (Primary Tumor).

*** Diagnosis/Diagnoses: ***

16-cm long large bowel resection specimen including a polypoid, moderately differentiated adenocarcinoma of the colorectal type with infiltration of the pericolic fatty tissue and with three regional lymph node metastases. Tumor-free large bowel resection margins. Tumor-free mesenteric resection margin. An inflammatory portion of the urinary bladder fused with the large bowel and a ductus deferens segment, adhering in the tumor area.

Tumor stage: pT3 pN1 (3/43) pMX; G2, L0 V0, local R0.

Source: NCI Genomic Data Commons file 050b38eb-d3ac-40fc-880b-59542058be6b (TCGA-AA-3519.127E9D44-2F7C-41F3-B925-D04812A8A9F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).